Somatic mutation profile of tumor specimen 0DEYDV from CCDI case PBBRGE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.2 years (1,527 days).
Specimen 0DEYDV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c289ccd2-523d-47b2-b945-187aa89bda0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEYDM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4912a141-0f44-46c1-8d14-dd81182b4bc6

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F2 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 104/532 reads (20%) | catalogued as rs762292061, CM138720, COSV61316792; called by muse, mutect2, varscan2
- INSRR | c.3680G>A p.R1227H | Missense Mutation (SNP) | VAF 96/589 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.376); catalogued as rs370122814; called by muse, mutect2, varscan2
- PITPNM1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs201959831, COSV62708361; called by muse, mutect2, varscan2
- PRKN | c.29G>C p.S10T | Missense Mutation (SNP) | VAF 35/1324 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV100629148; called by muse, mutect2
